Somatic mutation profile of cancer-model specimen HCM-BROD-0096-C15-85C (3D Organoid, passage 10; aliquot HCM-BROD-0096-C15-85C-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0096-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 48.6 years (17,748 days).
Specimen HCM-BROD-0096-C15-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a40243ec-a70b-4960-b247-f334c10d40d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0096-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0096-C15-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e39e7dd9-5279-46d9-95d7-a04c32a01c2e

The open-access MAF lists 265 somatic variants for this specimen: 188 protein-altering or splice-affecting, 67 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 67, Nonsense Mutation 8, Frame Shift Del 6, Intron 4, 5'Flank 2, 3'UTR 1, RNA 1, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 106/106 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519741, COSV61684436, COSV61688043; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TONSL | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 268/399 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1335783881, COSV68048183; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.3829G>A p.V1277I (on ENST00000265723 / NM_018849.3; = p.V1270I on NM_000443.4) | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as rs776326518; called by muse, mutect2, varscan2
- ACSF3 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 508/509 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs763823186, COSV58078060; called by muse, mutect2, varscan2
- ADGRL1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 176/177 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs549520700, COSV61564825, COSV99058042; called by muse, mutect2, varscan2
- AGTPBP1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV100430280, COSV61276121; called by muse, mutect2, varscan2
- ALDH18A1 | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 122/353 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569086681; called by muse, mutect2, varscan2
- AP1B1 | c.247A>T p.M83L | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT tolerated (1); PolyPhen possibly damaging (0.706); catalogued as COSV100434793; called by muse, mutect2, varscan2
- APOL3 | c.767C>G p.T256S (on ENST00000349314 / NM_145640.2; = p.T185S on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 155/321 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.078); catalogued as rs376117400; called by muse, mutect2, varscan2
- ARVCF | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs755701196; called by muse, varscan2
- CACNA1D | c.4184C>A p.A1395E (on ENST00000350061 / NM_001128840.3; = p.A1415E on NM_000720.4) | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55457005; called by muse, mutect2, varscan2
- CACNA1E | c.2957G>C p.S986T | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV62408040; called by muse, mutect2, varscan2
- CADM2 | c.142C>A p.Q48K (on ENST00000407528 / NM_001167674.2; = p.Q50K on NM_153184.4) | Missense Mutation (SNP) | VAF 148/291 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV67399488; called by muse, mutect2, varscan2
- CDH22 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 395/573 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs931213284; called by muse, mutect2, varscan2
- CHD3 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 162/321 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs138306277; called by muse, mutect2, varscan2
- CHTF18 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 182/284 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368315905; called by muse, mutect2, varscan2
- CTNNA2 | c.1257A>C p.Q419H | Missense Mutation (SNP) | VAF 162/314 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV58157947, COSV58167835; called by muse, mutect2, varscan2
- CTNND2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 134/394 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as COSV58871096; called by muse, mutect2, varscan2
- DDX23 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.973); catalogued as rs769587766, COSV57285269; called by muse, mutect2, varscan2
- DNAAF3 | c.266G>A p.R89Q (on ENST00000524407 / NM_001256715.2; = p.R136Q on NM_178837.4) | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1404783056; called by muse, mutect2, varscan2
- DNAH1 | c.4817A>G p.N1606S | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370587491; called by muse, mutect2, varscan2
- DTNA | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as rs199556035, COSV52008314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHD3 | c.1070A>T p.K357M | Missense Mutation (SNP) | VAF 169/350 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV59029883, COSV59031752; called by muse, mutect2, varscan2
- EYA4 | c.1067A>C p.K356T (on ENST00000531901 / NM_001301013.1; = p.K350T on NM_004100.5) | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV100766075; called by muse, mutect2, varscan2
- EYS | c.2725G>T p.V909F | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV101008344; called by muse, mutect2, varscan2
- FIGNL2 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 268/762 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1265061546; called by muse, mutect2, varscan2
- FSHR | c.317A>C p.N106T | Missense Mutation (SNP) | VAF 95/374 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV58630704; called by muse, mutect2, varscan2
- FSIP1 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs779379472; called by muse, mutect2, varscan2
- GLRA3 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 70/134 reads (52%) | catalogued as rs781425532, COSV56858434; called by muse, mutect2
- GPC5 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 221/347 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141328977, COSV65630065; called by muse, mutect2, varscan2
- IGFN1 | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99811437; called by mutect2, varscan2
- IKBKB | c.1393C>T p.L465F | Missense Mutation (SNP) | VAF 225/338 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.302); catalogued as rs1449893014; called by muse, mutect2, varscan2
- IL1RAPL2 | c.618A>C p.E206D | Missense Mutation (SNP) | VAF 145/297 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV61159481, COSV61185570; called by muse, mutect2, varscan2
- KCNA4 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs747368709, COSV60251092; called by muse, mutect2, varscan2
- KDM6A | c.3668G>T p.G1223V | Missense Mutation (SNP) | VAF 320/321 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65042064; called by muse, mutect2, varscan2
- KLF14 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 203/803 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1426874109, COSV100205937; called by muse, mutect2, varscan2
- KLHL5 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54671728; called by muse, mutect2, varscan2
- KRTAP23-1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 107/207 reads (52%) | PolyPhen probably damaging (0.988); catalogued as COSV100492619, COSV61935530; called by muse, mutect2, varscan2
- LPAR4 | c.1056A>C p.E352D | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.077); catalogued as COSV70912514, COSV70913189; called by muse, mutect2, varscan2
- LRRTM4 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 196/389 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297670, COSV69139188; called by muse, mutect2, varscan2
- MICAL2 | c.1287C>A p.N429K | Missense Mutation (SNP) | VAF 116/352 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1410860607; called by muse, varscan2
- MKRN3 | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 161/270 reads (60%) | PolyPhen possibly damaging (0.887); catalogued as COSV73742514; called by muse, mutect2, varscan2
- NLRP10 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 150/475 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs868321989; called by muse, mutect2, varscan2
- NME8 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 108/456 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52254619, COSV99553357, COSV99553951; called by muse, mutect2
- NME8 | c.1675A>C p.S559R | Missense Mutation (SNP) | VAF 110/489 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1330765391, COSV52246197, COSV52252862; called by muse, mutect2, varscan2
- OR10J3 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 110/479 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100171900; called by muse, mutect2, varscan2
- OR10X1 | c.628C>A p.H210N | Missense Mutation (SNP) | VAF 85/409 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1412721300, COSV100936720; called by muse, mutect2, varscan2
- OR10X1 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 85/410 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs771410129; called by muse, mutect2, varscan2
- OR11A1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 245/678 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs373751127; called by muse, mutect2, varscan2
- OR1S2 | c.616A>T p.M206L | Missense Mutation (SNP) | VAF 208/390 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs775290144, COSV56918768; called by muse, varscan2
- OR52N1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 100/329 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV57692824; called by muse, mutect2, varscan2
- OR6P1 | c.582A>C p.Q194H | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV58108666; called by muse, mutect2, varscan2
- OR8J3 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 179/261 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV56880395; called by muse, mutect2, varscan2
- PAPPA | c.1546T>G p.F516V | Missense Mutation (SNP) | VAF 198/316 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100074328; called by muse, mutect2, varscan2
- PCDHA9 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 240/656 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); catalogued as rs1554143525, COSV65327085; called by muse, mutect2, varscan2
- PCDHGA2 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 321/485 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99539933; called by muse, mutect2, varscan2
- PDE6A | c.2131G>C p.V711L | Missense Mutation (SNP) | VAF 181/270 reads (67%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.665); catalogued as COSV54925482; called by muse, mutect2, varscan2
- PIGB | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 111/196 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765017632; called by muse, mutect2, varscan2
- PKHD1L1 | c.11219C>T p.P3740L | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs761972959; called by muse, mutect2, varscan2
- PLCG2 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 347/348 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63868886; called by muse, mutect2, varscan2
- PLXND1 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 107/348 reads (31%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.494); catalogued as rs200800403; called by muse, mutect2, varscan2
- POM121L12 | c.56del p.G19Efs*15 | Frame Shift Del (DEL) | VAF 141/661 reads (21%) | catalogued as COSV68692587; called by mutect2, pindel, varscan2
- PPFIA4 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530132702, COSV55313115; called by muse, mutect2, varscan2
- PRAMEF17 | c.592T>G p.L198V | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.318); catalogued as COSV65816788; called by muse, mutect2, varscan2
- PROX1 | c.1597C>G p.L533V | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.075); catalogued as COSV99799537; called by muse, mutect2, varscan2
- PRSS33 | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 175/516 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.774); catalogued as COSV53451534; called by muse, mutect2, varscan2
- PTPRN | c.2419G>A p.V807I | Missense Mutation (SNP) | VAF 287/560 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201885534; called by muse, mutect2, varscan2
- PTPRT | c.2051A>G p.N684S | Missense Mutation (SNP) | VAF 115/343 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs111367672; called by muse, mutect2, varscan2
- PUM3 | c.1520C>G p.A507G | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV65896618; called by muse, mutect2, varscan2
- PUSL1 | c.389A>C p.Y130S | Missense Mutation (SNP) | VAF 183/627 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60087878; called by muse, mutect2, varscan2
- RBFOX3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 217/315 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV101332907; called by muse, mutect2, varscan2
- RNF130 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1359926306; called by muse, mutect2, varscan2
- ROS1 | c.3350del p.G1117Afs*2 | Frame Shift Del (DEL) | VAF 85/296 reads (29%) | catalogued as COSV100876534; called by mutect2, pindel, varscan2
- SFRP4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 451/607 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52262375; called by muse, mutect2, varscan2
- SLC16A12 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 153/417 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1190526514; called by muse, mutect2, varscan2
- SLC6A13 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58257343; called by muse, mutect2, varscan2
- SLITRK2 | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 143/287 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59423727; called by muse, mutect2, varscan2
- SPATA31D1 | c.3073C>G p.L1025V | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV61192941; called by muse, mutect2, varscan2
- SPSB4 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 182/602 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1236572137; called by muse, mutect2, varscan2
- SUGCT | c.1175A>C p.K392T (on ENST00000335693 / NM_001193313.2; = p.K418T on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV59334554; called by muse, mutect2, varscan2
- TACR3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs775705606, COSV59198526; called by muse, mutect2, varscan2
- TBCB | c.263T>C p.I88T | Missense Mutation (SNP) | VAF 102/209 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs954601005; called by muse, mutect2, varscan2
- TBX3 | c.1975G>A p.A659T (on ENST00000257566 / NM_016569.4; = p.A639T on NM_005996.4) | Missense Mutation (SNP) | VAF 220/689 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs1182290035; called by muse, varscan2
- TCP11L2 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs758990315; called by muse, mutect2, varscan2
- TFAP2D | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50414299; called by muse, mutect2, varscan2
- TIMELESS | c.3251C>G p.A1084G | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV57511094; called by muse, mutect2, varscan2
- TM9SF2 | c.1168T>C p.F390L | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs1269926541; called by muse, mutect2, varscan2
- TMEM132C | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 548/781 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs779428852; called by muse, mutect2
- TMPRSS15 | c.1496A>G p.Y499C | Missense Mutation (SNP) | VAF 132/255 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as rs767144283; called by muse, mutect2, varscan2
- TTK | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 165/261 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs1435699865; called by muse, mutect2, varscan2
- UNC13C | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 124/305 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768743988, COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- USP24 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 111/191 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs1463877069; called by muse, mutect2, varscan2
- VGLL2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 254/767 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.198); catalogued as COSV58309174; called by muse, mutect2, varscan2
- ZMYM6 | c.3176C>A p.S1059Y | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV64120682; called by muse, mutect2, varscan2
- ZNF415 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs548389733; called by muse, mutect2, varscan2
- ZNF517 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 383/583 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs767555825, COSV63464670; called by muse, mutect2, varscan2
- ABCC6 | c.1936C>T p.L646F | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.4166T>G p.L1389R | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRV1 | c.3370del p.E1124Sfs*3 | Frame Shift Del (DEL) | VAF 72/226 reads (32%) | called by mutect2, pindel*, varscan2
- ANK3 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF2 | c.2495C>T p.A832V (on ENST00000361247 / NM_001162383.2; = p.A804V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 209/769 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ARID2 | c.5222T>G p.L1741R | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- ARNT2 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 204/332 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ATP6V1H | c.587del p.Q196Rfs*12 | Frame Shift Del (DEL) | VAF 67/223 reads (30%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.3842C>T p.S1281F | Missense Mutation (SNP) | VAF 183/291 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- BAZ2A | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- BEST4 | c.665G>C p.S222T | Missense Mutation (SNP) | VAF 143/456 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- BRAF | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 139/485 reads (29%) | called by muse, mutect2, varscan2
- CAVIN2 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 138/635 reads (22%) | called by muse, mutect2, varscan2
- CCAR2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCDC50 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CD5L | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CEP104 | c.2368G>T p.V790F | Missense Mutation (SNP) | VAF 181/298 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CLCN5 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL11A1 | c.4289C>A p.P1430Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- COL12A1 | c.2338G>T p.E780* | Nonsense Mutation (SNP) | VAF 295/428 reads (69%) | called by muse, mutect2, varscan2
- CSMD3 | c.4205C>T p.A1402V (on ENST00000297405 / NM_001363185.1; = p.A1298V on NM_052900.3) | Missense Mutation (SNP) | VAF 166/256 reads (65%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CYYR1 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DEAF1 | c.1313C>G p.P438R | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKI | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLEC1 | c.4521G>T p.K1507N | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DNAJC10 | c.433T>A p.S145T | Missense Mutation (SNP) | VAF 167/394 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DNALI1 | c.677A>T p.E226V (on ENST00000296218; = p.E204V on NM_003462.5) | Missense Mutation (SNP) | VAF 123/360 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- DYNC2I1 | c.2671C>A p.Q891K | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EYA4 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM135A | c.3303A>T p.E1101D (on ENST00000370479 / NM_001351599.1; = p.E888D on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FCRLA | c.791A>C p.E264A (on ENST00000367959; = p.E241A on NM_032738.4) | Missense Mutation (SNP) | VAF 118/567 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FZD9 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 191/731 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABBR2 | c.1765A>T p.K589* | Nonsense Mutation (SNP) | VAF 109/181 reads (60%) | called by muse, mutect2, varscan2
- GALNTL6 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 108/199 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GLCE | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- GLOD4 | c.308G>A p.G103E (on ENST00000301328 / NM_001366247.1; = p.G88E on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGA6L4 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 354/645 reads (55%) | called by muse, mutect2, varscan2
- HDAC6 | c.3182A>T p.E1061V | Missense Mutation (SNP) | VAF 117/263 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HMCN1 | c.12069A>C p.K4023N | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXA4 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 262/910 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.05); called by muse, mutect2
- IL1RAPL2 | c.1756T>C p.S586P | Missense Mutation (SNP) | VAF 226/436 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ISL1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 321/483 reads (66%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- KCP | c.4019C>T p.A1340V (on ENST00000620378; = p.A1464V on NM_001366122.1) | Missense Mutation (SNP) | VAF 400/844 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIF18B | c.1771C>T p.P591S (on ENST00000593135 / NM_001265577.2; = p.P603S on NM_001264573.2) | Missense Mutation (SNP) | VAF 121/430 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KLK9 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 153/321 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KPNA1 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP29-1 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 160/539 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- KRTAP4-4 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 159/483 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- KRTAP5-11 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 185/675 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LNP1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 105/380 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, mutect2
- LRRD1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 75/386 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MDH1B | c.1091A>C p.N364T | Missense Mutation (SNP) | VAF 120/449 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MFAP3L | c.1131G>C p.E377D | Missense Mutation (SNP) | VAF 193/347 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MUC4 | c.3158A>G p.D1053G | Missense Mutation (SNP) | VAF 130/612 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.55); called by muse, varscan2
- NAPRT | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 220/686 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAP1 | c.2726A>C p.K909T | Missense Mutation (SNP) | VAF 201/355 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NR0B1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 261/578 reads (45%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NTM | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NTRK3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 184/279 reads (66%) | SIFT tolerated (0.59); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR13C8 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR6Y1 | c.937A>T p.R313* | Nonsense Mutation (SNP) | VAF 111/233 reads (48%) | called by muse, mutect2, varscan2
- OTP | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 212/710 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAWR | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 120/191 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHGC3 | c.2360A>C p.N787T | Missense Mutation (SNP) | VAF 185/570 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PLEKHS1 | c.671C>T p.A224V (on ENST00000369310 / NM_182601.1; = p.A230V on NM_024889.5) | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PLXDC2 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 101/342 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PTPRG | c.2205G>A p.M735I | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SCGN | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC16A | c.2165C>A p.A722E | Missense Mutation (SNP) | VAF 130/474 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SETBP1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SF3A2 | c.1044del p.G349Efs*97 | Frame Shift Del (DEL) | VAF 93/313 reads (30%) | called by pindel, varscan2
- SLC1A3 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 176/298 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SMARCAL1 | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SOX3 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 232/504 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A1 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 78/303 reads (26%) | called by muse, mutect2, varscan2
- SPRED3 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 427/427 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT16H | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 94/179 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TEX12 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TFAP2A | c.1282G>A p.A428T (on ENST00000482890; = p.A420T on NM_001032280.3) | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNC | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 279/449 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPP2 | c.3635_3636del p.K1212Rfs*23 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | called by mutect2, pindel, varscan2
- TTLL4 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 276/565 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TUBA3E | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 256/571 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- UBQLN3 | c.1506A>C p.Q502H | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC5B | c.2548C>A p.Q850K | Missense Mutation (SNP) | VAF 145/434 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VSIG10 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 158/459 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- VSTM4 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- WDFY3 | c.9267C>A p.N3089K | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, varscan2
- ZIM3 | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF615 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 121/287 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ZNF736 | c.1168_1172dup p.H391Qfs*56 | Frame Shift Ins (INS) | VAF 65/370 reads (18%) | called by mutect2, pindel, varscan2
- ZNF800 | c.1463G>T p.C488F | Missense Mutation (SNP) | VAF 113/486 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- A1CF | c.618A>G p.L206= | Silent (SNP) | VAF 138/220 reads (63%) | catalogued as COSV99255348; called by muse, mutect2, varscan2
- ABI2 | c.15G>A p.Q5= | Silent (SNP) | VAF 285/613 reads (46%) | called by muse, mutect2, varscan2
- ACTC1 | c.774C>T p.R258= | Silent (SNP) | VAF 108/200 reads (54%) | catalogued as COSV51757879; called by muse, mutect2, varscan2
- ARVCF | c.1368G>T p.R456= | Silent (SNP) | VAF 103/234 reads (44%) | called by muse, varscan2
- ASCC3 | c.4977A>G p.L1659= | Silent (SNP) | VAF 70/219 reads (32%) | called by muse, mutect2, varscan2
- ASPM | c.5598T>C p.D1866= | Silent (SNP) | VAF 235/343 reads (69%) | catalogued as rs1393085391; called by muse, mutect2, varscan2
- ATRNL1 | c.4131T>C p.T1377= | Silent (SNP) | VAF 48/215 reads (22%) | called by muse, mutect2, varscan2
- C6orf118 | c.1269A>G p.S423= | Silent (SNP) | VAF 146/205 reads (71%) | called by muse, mutect2, varscan2
- CCDC33 | c.180G>A p.V60= | Silent (SNP) | VAF 120/209 reads (57%) | called by muse, mutect2, varscan2
- CEP135 | c.1434C>T p.S478= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as rs201737230; called by muse, mutect2, varscan2
- CHRDL1 | c.1068A>G p.R356= (on ENST00000372045; = p.R362= on NM_145234.4) | Silent (SNP) | VAF 162/345 reads (47%) | catalogued as rs891337283; called by muse, mutect2, varscan2
- CHRM1 | c.1140G>A p.P380= | Silent (SNP) | VAF 153/462 reads (33%) | catalogued as rs373622413; called by muse, mutect2, varscan2
- CHST13 | c.390A>G p.Q130= | Silent (SNP) | VAF 320/508 reads (63%) | called by muse, mutect2, varscan2
- CLEC16A | c.1476G>A p.P492= | Silent (SNP) | VAF 191/277 reads (69%) | catalogued as rs200520670; called by muse, mutect2, varscan2
- CLIP1 | c.3027G>A p.S1009= (on ENST00000620786 / NM_001247997.1; = p.S998= on NM_002956.2) | Silent (SNP) | VAF 76/285 reads (27%) | catalogued as rs372055105; called by muse, mutect2, varscan2
- CNNM4 | c.2202C>T p.D734= | Silent (SNP) | VAF 305/598 reads (51%) | catalogued as rs552599408; called by muse, mutect2, varscan2
- CNTLN | c.1422A>G p.K474= | Silent (SNP) | VAF 88/269 reads (33%) | called by muse, mutect2, varscan2
- CPXCR1 | c.642A>C p.S214= | Silent (SNP) | VAF 286/288 reads (99%) | called by muse, mutect2, varscan2
- CRTAC1 | c.1152C>T p.H384= | Silent (SNP) | VAF 135/385 reads (35%) | catalogued as rs566547089, COSV54010274; called by muse, mutect2, varscan2
- DCBLD2 | c.39G>A p.P13= | Silent (SNP) | VAF 146/470 reads (31%) | called by muse, varscan2
- DNAH11 | c.2838A>G p.A946= | Silent (SNP) | VAF 386/511 reads (76%) | called by muse, mutect2, varscan2
- DNPEP | c.207G>A p.K69= | Silent (SNP) | VAF 82/364 reads (23%) | called by muse, mutect2, varscan2
- EPHA10 | c.435C>T p.G145= | Silent (SNP) | VAF 136/476 reads (29%) | catalogued as COSV60403421; called by muse, mutect2, varscan2
- ERBB3 | c.3531T>G p.L1177= | Silent (SNP) | VAF 93/308 reads (30%) | called by muse, mutect2, varscan2
- FMN2 | c.912G>A p.A304= | Silent (SNP) | VAF 246/674 reads (36%) | catalogued as rs1240395843, COSV60415194; called by muse, varscan2
- FPGT-TNNI3K | c.867G>A p.A289= | Silent (SNP) | VAF 106/323 reads (33%) | catalogued as rs188990439; called by muse, mutect2, varscan2
- HLA-DPB1 | c.342G>A p.G114= | Silent (SNP) | VAF 156/500 reads (31%) | called by muse, mutect2, varscan2
- IBSP | c.813C>T p.Y271= | Silent (SNP) | VAF 142/273 reads (52%) | catalogued as rs1304341987, COSV56895135; called by muse, mutect2, varscan2
- IKZF1 | c.1038G>A p.P346= | Silent (SNP) | VAF 190/793 reads (24%) | catalogued as COSV58784669; called by muse, mutect2, varscan2
- INSRR | c.3519G>A p.S1173= | Silent (SNP) | VAF 189/370 reads (51%) | catalogued as rs761696263; called by muse, mutect2, varscan2
- KIF3B | c.561G>T p.V187= | Silent (SNP) | VAF 237/357 reads (66%) | called by muse, mutect2, varscan2
- MMS19 | c.228A>G p.L76= | Silent (SNP) | VAF 97/320 reads (30%) | catalogued as rs549378336; called by muse, mutect2, varscan2
- MPPED2 | c.741C>G p.L247= | Silent (SNP) | VAF 97/317 reads (31%) | catalogued as rs767795394; called by muse, mutect2, varscan2
- MTTP | c.75T>C p.G25= | Silent (SNP) | VAF 74/158 reads (47%) | called by muse, varscan2
- MYH4 | c.384C>G p.P128= | Silent (SNP) | VAF 85/206 reads (41%) | catalogued as rs759413209; called by muse, mutect2, varscan2
- MYH6 | c.2841C>T p.D947= | Silent (SNP) | VAF 250/250 reads (100%) | catalogued as rs140305424; ClinVar: likely benign; called by muse, varscan2
- MYH9 | c.4830C>A p.A1610= | Silent (SNP) | VAF 334/334 reads (100%) | called by muse, mutect2, varscan2
- NCKAP5 | c.4968C>T p.I1656= | Silent (SNP) | VAF 200/449 reads (45%) | catalogued as rs766384798, COSV58430090; called by muse, mutect2, varscan2
- NRXN2 | c.579C>A p.G193= | Silent (SNP) | VAF 211/641 reads (33%) | called by muse, mutect2, varscan2
- NYX | c.792C>T p.N264= | Silent (SNP) | VAF 502/502 reads (100%) | catalogued as rs62637032, CM003276, COSV61181155; called by muse, mutect2, varscan2
- OR14K1 | c.804A>T p.L268= | Silent (SNP) | VAF 113/374 reads (30%) | catalogued as COSV51722125; called by muse, mutect2, varscan2
- OR5H14 | c.66G>A p.Q22= | Silent (SNP) | VAF 85/373 reads (23%) | catalogued as rs1253654958; called by muse, mutect2, varscan2
- PAPPA | c.106C>A p.R36= | Silent (SNP) | VAF 154/203 reads (76%) | called by muse, mutect2, varscan2
- PARP1 | c.2655C>T p.P885= | Silent (SNP) | VAF 81/219 reads (37%) | catalogued as rs373903460; called by muse, varscan2
- PAX7 | c.600C>T p.D200= | Silent (SNP) | VAF 194/280 reads (69%) | catalogued as rs777816122; called by muse, mutect2, varscan2
- PCDHB13 | c.2382G>T p.G794= | Silent (SNP) | VAF 59/204 reads (29%) | catalogued as rs781906402; called by muse, mutect2, varscan2
- PGAP1 | c.1161G>A p.Q387= | Silent (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- PHRF1 | c.1065C>T p.S355= | Silent (SNP) | VAF 333/494 reads (67%) | catalogued as rs781243340; called by muse, mutect2, varscan2
- PIP5K1A | c.912C>G p.L304= (on ENST00000368888 / NM_001135638.2; = p.L291= on NM_003557.3) | Silent (SNP) | VAF 87/388 reads (22%) | catalogued as COSV62958941; called by muse, mutect2, varscan2
- RBM27 | c.1431C>G p.T477= | Silent (SNP) | VAF 89/274 reads (32%) | catalogued as rs993674837, COSV99505988; called by muse, mutect2, varscan2
- TCERG1L | c.618T>C p.A206= | Silent (SNP) | VAF 110/379 reads (29%) | catalogued as COSV64059172; called by muse, mutect2, varscan2
- TCF20 | c.3234T>G p.G1078= | Silent (SNP) | VAF 437/439 reads (100%) | called by muse, mutect2, varscan2
- TECTA | c.6378T>G p.S2126= | Silent (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- TEX13C | c.1305G>A p.G435= | Silent (SNP) | VAF 140/323 reads (43%) | called by muse, mutect2, varscan2
- TGM6 | c.1134C>T p.R378= | Silent (SNP) | VAF 231/395 reads (58%) | catalogued as rs749044326; called by muse, mutect2, varscan2
- TLDC2 | c.219C>T p.T73= | Silent (SNP) | VAF 197/310 reads (64%) | catalogued as rs760164325, COSV54113669, COSV54114900; called by muse, mutect2, varscan2
- TMEM131 | c.5595G>T p.T1865= | Silent (SNP) | VAF 255/532 reads (48%) | called by muse, mutect2, varscan2
- TMEM271 | c.294C>T p.P98= | Silent (SNP) | VAF 233/421 reads (55%) | catalogued as rs1003798830; called by muse, mutect2, varscan2
- TMPRSS11D | c.1185G>T p.L395= | Silent (SNP) | VAF 131/282 reads (46%) | called by muse, mutect2, varscan2
- TRO | c.840C>T p.V280= | Silent (SNP) | VAF 302/302 reads (100%) | catalogued as COSV51504360; called by muse, mutect2, varscan2
- TRPC7 | c.876C>T p.N292= | Silent (SNP) | VAF 145/484 reads (30%) | catalogued as rs574852917, COSV61452561; called by muse, varscan2
- VPS13D | c.11712C>T p.I3904= | Silent (SNP) | VAF 93/308 reads (30%) | catalogued as rs202027166; called by muse, mutect2, varscan2
- VSIG10L2 | c.2199T>A p.T733= | Silent (SNP) | VAF 109/308 reads (35%) | called by muse, mutect2, varscan2
- YAP1 | c.1497C>T p.S499= (on ENST00000282441 / NM_001130145.3; = p.S445= on NM_006106.5) | Silent (SNP) | VAF 49/200 reads (25%) | called by muse, mutect2, varscan2
- ZNF106 | c.1086G>T p.S362= | Silent (SNP) | VAF 123/326 reads (38%) | called by muse, mutect2, varscan2
- ZNF681 | c.1365T>C p.C455= | Silent (SNP) | VAF 125/126 reads (99%) | catalogued as rs369101200; called by muse, mutect2, varscan2
- ZNF804B | c.729A>G p.E243= | Silent (SNP) | VAF 86/386 reads (22%) | catalogued as COSV60832705, COSV60849147; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58839715 C>T | 5'Flank (SNP) | VAF 161/748 reads (22%) | catalogued as rs1293772348; called by muse, mutect2, varscan2
- CDH11 | c.-136A>G | 5'UTR (SNP) | VAF 115/349 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | n.6675G>T | RNA (SNP) | VAF 128/238 reads (54%) | called by muse, mutect2, varscan2
- GALNTL6 | c.139-177173G>A | Intron (SNP) | VAF 101/214 reads (47%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1836+29864T>C | Intron (SNP) | VAF 116/179 reads (65%) | called by muse, mutect2, varscan2
- JAK3 | c.3207+28T>A | Intron (SNP) | VAF 212/432 reads (49%) | called by muse, mutect2, varscan2
- SYNC | c.*26G>A | 3'UTR (SNP) | VAF 84/279 reads (30%) | catalogued as rs766792483; called by muse, mutect2, varscan2
- TTN | c.10361-4745T>C | Intron (SNP) | VAF 74/348 reads (21%) | catalogued as rs764757734; called by muse, mutect2, varscan2
- TULP4 | chr6:158312120 C>T | 5'Flank (SNP) | VAF 118/362 reads (33%) | catalogued as rs933172899; called by muse, varscan2
- ZNF517 | chr8:144810189 G>A | 3'Flank (SNP) | VAF 306/474 reads (65%) | catalogued as rs1414047421; called by muse, varscan2
